Somatic mutation profile of tumor specimen MMRF_1478_1_BM_CD138pos (aliquot MMRF_1478_1_BM_CD138pos_T1_KAS5U_L01922) from MMRF case MMRF_1478, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.1 years (17,563 days).
Specimen MMRF_1478_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23d7b521-84c9-43a7-99a3-a5504bef9857.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1478_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1478_1_PB_CD3pos_C2_KAS5U_L01933; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ea17acc-9c5d-465c-80de-1954ae8c8ed3

The open-access MAF lists 68 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 22, Intron 5, Silent 5, RNA 4, 3'Flank 2, Splice Region 2, 5'UTR 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 65/148 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- DPY19L2P1 | n.1812-4dup | Splice Region (INS) | VAF 84/200 reads (42%) | catalogued as rs748394838; called by mutect2, varscan2
- LILRB5 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs769256920, COSV60256311; called by muse, mutect2, varscan2
- NACC2 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.859); catalogued as rs771699533; called by muse, mutect2, varscan2
- PLG | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM068063, CM068064; called by muse, mutect2, varscan2
- PTPRT | c.2662G>C p.G888R | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61998414; called by muse, mutect2, varscan2
- RNH1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs577864215, COSV62250826; called by muse, mutect2, varscan2
- SPATA18 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs372883266; called by muse, mutect2, varscan2
- ST8SIA5 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 20/151 reads (13%) | PolyPhen possibly damaging (0.536); catalogued as rs777597828; called by muse, mutect2, varscan2
- TPR | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs773662466, COSV66601914; called by muse, mutect2, varscan2
- TYRP1 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 174/324 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66358285; called by muse, mutect2, varscan2
- ADAMTS5 | c.1270_1273del p.K424Sfs*14 | Frame Shift Del (DEL) | VAF 31/55 reads (56%) | called by mutect2, pindel, varscan2
- CFAP221 | c.1781A>C p.K594T | Missense Mutation (SNP) | VAF 176/337 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CWF19L2 | c.2591G>A p.G864D | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- CYP4F22 | c.-1G>T | Splice Region (SNP) | VAF 67/110 reads (61%) | called by muse, mutect2, varscan2
- HNRNPL | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- INTS6 | c.6_11del p.I3_L4del | In Frame Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- ITGAD | c.2697-1G>A p.X899_splice | Splice Site (SNP) | VAF 92/193 reads (48%) | called by muse, mutect2, varscan2
- PLCL1 | c.1160A>C p.D387A | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RRM2B | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RSF1 | c.1899T>A p.N633K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMAD7 | c.914A>T p.N305I | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SPRED3 | c.11T>G p.V4G | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TFR2 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIFAB | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TMEM247 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); called by muse, varscan2
- UBE2D1 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by mutect2, varscan2
- VSTM4 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFR2 | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DSG4 | c.210T>C p.I70= | Silent (SNP) | VAF 103/208 reads (50%) | called by muse, mutect2, varscan2
- HERC2 | c.4308C>T p.V1436= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs779001002, COSV55328506; called by mutect2, varscan2
- LRP1B | c.930T>C p.C310= | Silent (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1674C>T p.N558= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53908667; called by muse, mutect2, varscan2
- TRAFD1 | c.1188A>G p.A396= | Silent (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*2514T>A | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- B3GNT6 | c.*940A>T | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- BARD1 | c.*1561C>T | 3'UTR (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- BMI1 | c.*1098del | 3'UTR (DEL) | VAF 51/120 reads (43%) | called by mutect2, pindel, varscan2
- CACNA1B | c.*391G>A | 3'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as rs201672561; called by muse, mutect2, varscan2
- CD47 | c.*962T>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- CRIM1 | c.332-18229T>C | Intron (SNP) | VAF 156/341 reads (46%) | called by muse, mutect2, varscan2
- FZD8 | c.*601_*602insG | 3'UTR (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- GABRA2 | c.187+20720T>A | Intron (SNP) | VAF 60/95 reads (63%) | called by muse, mutect2, varscan2
- HCRTR2 | c.*151del | 3'UTR (DEL) | VAF 32/67 reads (48%) | catalogued as rs979702175; called by mutect2, varscan2
- HERC2P3 | n.2309G>T | RNA (SNP) | VAF 50/413 reads (12%) | catalogued as rs762458368; called by muse, mutect2, varscan2
- KCNB1 | c.*635C>G | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- LILRB4 | c.*4A>T | 3'UTR (SNP) | VAF 137/313 reads (44%) | catalogued as COSV99553630; called by muse, mutect2, varscan2
- LINC00922 | n.782C>A | RNA (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- MCM7 | c.*20del | 3'UTR (DEL) | VAF 66/138 reads (48%) | catalogued as rs1287690369; called by mutect2, varscan2
- MIR924 | n.18T>C | RNA (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- MYADML | n.615C>T | RNA (SNP) | VAF 58/372 reads (16%) | called by muse, mutect2, varscan2
- MYOCD | c.*5190G>C | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- PCDHB3 | c.*740T>C | 3'UTR (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- PDE6A | c.*2766G>A | 3'UTR (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- PPP1R3G | c.*378T>C | 3'UTR (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- PPP6C | c.*2968G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- RTN4 | c.3478-17_3478-14dup | Intron (INS) | VAF 56/139 reads (40%) | called by mutect2, pindel, varscan2
- SEMA3A | c.*2482G>A | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*1813C>T | 3'UTR (SNP) | VAF 65/132 reads (49%) | catalogued as rs984826567, COSV100287763; called by muse, mutect2, varscan2
- SLC17A6 | c.*1260T>A | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- SOS1 | c.*3774A>T | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- SYNM | c.*1974C>G | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2
- TFCP2 | c.-489A>G | 5'UTR (SNP) | VAF 131/252 reads (52%) | called by muse, mutect2, varscan2
- TPO | c.2748+546C>G | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2
- TSSK4 | chr14:24208255 T>A | 3'Flank (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- USP34 | chr2:61183610 C>G | 3'Flank (SNP) | VAF 12/67 reads (18%) | called by muse, varscan2
- ZNF394 | c.583+16C>G | Intron (SNP) | VAF 89/201 reads (44%) | called by muse, mutect2, varscan2
- ZNF587 | c.*4239C>G | 3'UTR (SNP) | VAF 66/152 reads (43%) | catalogued as rs545042929; called by muse, varscan2
